Somatic mutation profile of tumor specimen TCGA-YL-A9WY-01A (aliquot TCGA-YL-A9WY-01A-11D-A41K-08) from TCGA case TCGA-YL-A9WY, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.9 years (21,164 days).
Specimen TCGA-YL-A9WY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb068669-4bbd-46af-b6c0-fd8e8d0b5d35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A9WY-10A (Blood Derived Normal), aliquot TCGA-YL-A9WY-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2965bb2-4edc-48de-98ec-16f902f2a8ec

The open-access MAF lists 34 somatic variants for this specimen: 25 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 24, Silent 9, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 7/55 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PROKR2 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138672528, CM083838; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPATA5 | c.269G>T p.S90I | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs796051893, CM159205, COSV99916360; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.530C>G p.P177R | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs751477326, CM102507, COSV52661381, COSV52721872, COSV52783879; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BBS9 | c.2471G>A p.R824H (on ENST00000242067 / NM_001348036.1; = p.R784H on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs376641244, COSV99629929; called by muse, mutect2, varscan2
- C7orf31 | c.835A>G p.T279A | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV99384154; called by muse, mutect2, varscan2
- CAPN15 | c.3119A>G p.N1040S | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.985); catalogued as COSV99562807; called by muse, mutect2, varscan2
- CCDC171 | c.3842T>C p.L1281S | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101048765; called by muse, mutect2, varscan2
- CSMD1 | c.10361A>T p.D3454V (on ENST00000520002; = p.D3453V on NM_033225.6) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV100153431; called by muse, mutect2, varscan2
- CTNND1 | c.1006T>C p.W336R | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV100650271; called by muse, mutect2, varscan2
- FANCM | c.1622T>C p.V541A | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57509231; called by muse, mutect2
- IGKV1-9 | c.211T>C p.Y71H | Missense Mutation (SNP) | VAF 49/224 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.168); catalogued as rs573323375; called by muse, mutect2, varscan2
- ITGA7 | c.2327C>T p.A776V (on ENST00000555728; = p.A732V on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs368879643, COSV57691178; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MBOAT1 | c.1085A>G p.Y362C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100209195; called by muse, mutect2
- MED12 | c.3668T>G p.V1223G | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61339738; called by muse, mutect2, varscan2
- NXPE4 | c.1063C>T p.R355C (on ENST00000375478 / NM_001077639.2; = p.R71C on NM_017678.3) | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as rs201579260, COSV100970308; called by muse, mutect2
- PCDHGB2 | c.1540G>C p.V514L | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.533); catalogued as rs1247091931, COSV54045707, COSV99546445; called by muse, mutect2, varscan2
- PITRM1 | c.2596G>A p.V866M | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.404); catalogued as rs371412408; called by muse, mutect2, varscan2
- POLR2B | c.2843A>G p.Q948R | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1188347706, COSV100108344; called by muse, mutect2, varscan2
- SEMA4F | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs749568015, COSV100336146; called by muse, mutect2, varscan2
- SPEG | c.8524C>G p.P2842A | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV100405592; called by muse, mutect2
- SYNPO | c.896C>T p.P299L (on ENST00000394243 / NM_001166208.2; = p.P55L on NM_007286.6) | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.179); catalogued as rs763541477, COSV100302425; called by muse, mutect2, varscan2
- TARS1 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs996780252, COSV99466455; called by muse, mutect2, varscan2
- TMEM260 | c.718T>C p.S240P | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.975); catalogued as COSV99840650; called by muse, mutect2, varscan2
- MYBL1 | c.884del p.S295Lfs*17 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, pindel
- ASAP1 | c.1824C>T p.A608= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs371153344; called by muse, mutect2, varscan2
- CATSPER1 | c.1017C>T p.P339= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs780744408, COSV100376228; called by muse, mutect2, varscan2
- CLCNKA | c.276G>A p.R92= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100510330; called by muse, mutect2, varscan2
- CRACDL | c.471C>T p.D157= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs751150288, COSV67406610; called by muse, mutect2, varscan2
- HGF | c.1452A>C p.V484= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs759566751, COSV99738426; called by muse, mutect2, varscan2
- IPO8 | c.2601C>T p.F867= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as rs373155571, COSV99805639; called by muse, varscan2
- KIF5A | c.1245G>A p.Q415= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99673563; called by muse, mutect2, varscan2
- PLCG2 | c.408G>A p.A136= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs747155855, COSV63870280; called by muse, mutect2, varscan2
- ZMIZ2 | c.1020C>T p.G340= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs756330810, COSV54808632; called by mutect2, varscan2
